Gene-level copy-number profile of tumor specimen TCGA-RD-A8N1-01A from TCGA case TCGA-RD-A8N1, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 70.5 years (25,737 days).
Specimen TCGA-RD-A8N1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.baf22fa0-4c7d-472a-976b-2827a65eb602.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RD-A8N1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/45f2a556-6149-459c-9e9e-96a9a7e01a9c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 6,227; copy number 2: 32,182; copy number 3: 13,579; copy number 4: 6,822; copy number 5: 779; copy number 6: 173; copy number 8: 4; copy number 17: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RD-A8N1-01A-12D-A363-01): tumor purity 0.28, ploidy 2.59, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:4,269,153–4,493,163, 4 genes: AC023483.1, SETMAR, MRPS10P2, ITPR1-DT.
- chr7:110,108,031–110,534,757, 2 genes (within-gene range 0–2): AC073114.1, AC073114.2.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,892,188–22,214,672, 11 genes: AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr15:94,455,469–95,507,865, 14 genes: AC009432.2, LINC02852, AC009432.1, AC022308.1, AC087633.2, AC107976.1, AC087633.1, AC087636.1, LINC01197, AC104260.1, AC104260.2, AC104260.3, LINC00924, AC027013.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 959 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:106,449,775–113,947,174, 132 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:167,864,773–198,222,513, 605 genes, copy number 5–6 (broad region; genes not listed).
- chr5:144,856,890–145,381,670, 4 genes, copy number 8 (within-gene range 5–8): AC132803.1, NAMPTP2, ASS1P10, AC137770.1.
- chr7:67,691,058–70,838,013, 22 genes, copy number 6: AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3, AC004910.1, RNA5SP231, AC104688.1, RNU6-832P, AC069280.2, AC092100.1, AC069280.1, MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66, AUTS2, AC073873.1.
- chr11:89,177,875–98,131,198, 193 genes, copy number 5 (broad region; genes not listed).
- chr18:73,324,941–73,745,232, 3 genes, copy number 17: LINC02582, AC079070.1, RN7SL401P.

Autosomal genes at a single copy (total copy number 1): 3,853. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
